Gene-level copy-number profile of tumor specimen TCGA-56-8626-01A from TCGA case TCGA-56-8626, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.0 years (21,908 days).
Specimen TCGA-56-8626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1129d851-07ef-47de-884e-647b60583195.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8626-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5bab4800-71a9-4faa-b899-16c8bcc9af9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,885; copy number 2: 34,504; copy number 3: 5,652; copy number 4: 4,090; copy number 5: 965; copy number 6: 2; copy number 12: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8626-01A-11D-2391-01): tumor purity 0.4, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,677 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,670,878–198,222,513, 636 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 12 (broad region; genes not listed).
- chr7:20,615,207–20,777,038, 1 gene, copy number 5 (within-gene range 4–5): ABCB5.
- chr7:20,782,279–37,449,249, 328 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:29,636,486–29,826,711, 2 genes, copy number 6: AL354676.1, ME2P1.

Autosomal genes at a single copy (total copy number 1): 11,464. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
